Gene-level copy-number profile of tumor specimen HCM-CSHL-0403-C25-01B from HCMI case HCM-CSHL-0403-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 63.9 years (23,352 days).
Specimen HCM-CSHL-0403-C25-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file da7a35e1-801b-487a-9306-8a52b0539a97.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0403-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/f17131b4-324d-494e-ac80-08ba3bc9149b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 58; copy number 1: 9,375; copy number 2: 44,957; copy number 3: 4,495; copy number 4: 16; copy number 5: 8.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,636,604–10,796,650, 2 genes: CASZ1, AL139423.1.
- chr1:16,014,028–16,057,308, 4 genes: HSPB7, CLCNKA, AL355994.2, CLCNKB.
- chr1:16,974,502–17,011,928, 5 genes: MFAP2, AL049569.2, AL049569.1, ATP13A2, AL049569.3.
- chr1:43,991,359–44,031,467, 2 genes (within-gene range 0–2): CCDC24, SLC6A9.
- chr2:72,129,238–72,148,038, 1 gene: CYP26B1.
- chr2:232,442,034–232,447,418, 1 gene: DIS3L2P1.
- chr5:139,648,999–139,649,728, 1 gene (within-gene range 0–1): CXXC5-AS1.
- chr6:170,160,606–170,200,258, 3 genes: AL596442.1, AL596442.2, RPL12P23.
- chr7:128,850,162–128,910,719, 4 genes (within-gene range 0–2): FLNC-AS1, KCP, ATP6V1F, ATP6V1FNB.
- chr9:130,892,707–130,896,812, 1 gene: QRFP.
- chr10:38,403,189–38,452,153, 1 gene (within-gene range 0–2): AL133216.2.
- chr10:38,452,987–38,455,365, 1 gene (within-gene range 0–2): CICP9.
- chr12:47,826,854–47,837,898, 1 gene (within-gene range 0–1): LINC02354.
- chr15:62,244,330–62,270,680, 3 genes (within-gene range 0–2): Metazoa_SRP, GOLGA2P11, AC126323.4.
- chr17:1,934,677–2,025,334, 4 genes: RTN4RL1, AC099684.2, AC099684.1, AC099684.3.
- chr17:18,108,706–18,268,828, 7 genes (within-gene range 0–1): MYO15A, AC087164.1, ALKBH5, LLGL1, FLII, MIEF2, AC127537.1.
- chr18:79,420,836–79,422,780, 1 gene (within-gene range 0–1): AC018445.3.
- chr19:4,969,113–5,153,598, 1 gene: KDM4B.
- chr19:56,132,599–56,160,893, 2 genes: ZNF444, AC024580.1.
- chr21:45,478,266–45,478,326, 1 gene (within-gene range 0–1): MIR6815.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:10,612,455–13,120,807, 8 genes, copy number 5: SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 6,570. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
